Surgical pathology report (de-identified scan), TCGA case TCGA-EE-A20B, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Sydney, specimen TCGA-EE-A20B-06A (Metastatic).

DOB/Age/Sex: years Female
Location:
Requested by:
Requested on:
Specimen Rcvd:
Accession No.:
Copies to:

HISTOPATHOLOGY REPORT

REFERRED MRN

ICD-0-3
Melanoma, NOS 8720/3
Site: Skin, thigh C44.7 hr 3/30/11

CLINICAL DETAILS

?Recurrent melanoma at primary site L posterolateral thigh (original wide excision several years ago).
1. Wide excision specimen L thigh. 2. Sentinel node L groin.

MACROSCOPIC DESCRIPTION

(Dr

Two specimens were received.

1. "TUMOUR LEFT THIGH". An unorientated ellipse of skin 115 x 35mm to a depth of up to 16mm. On the surface is an indurated area possibly previous scar 35x6mm. The skin surrounding this area contains blue dye. Serial sectioning beneath the scar in the fatty tissue is a well circumscribed tan nodule 20x20x18mm. It comes to within 10mm of the closest surgical margin. Two sections of the nodule with the closest margin embedded in two blocks.

2. "SENTINEL NODE LEFT GROIN NO. 1". One pale blue node up to 11mm across. Bisected and all embedded in one block. HMB45 and S100 ordered.

MICROSCOPIC REPORT

1. Skin, left thigh

Location of tumour: dermis subcutaneous tissue

Size of tumour: ~20 x 20 x 18mm (macroscopic)

Tumour description: nests and sheets of pleomorphic, mitotically active (up to 17 per mm²) epithelioid and spindle cells

Distance to nearest margin: ~5mm (deep)

Other comments: the features are in keeping with melanoma; as the tumour does not show an epidermal connection and a junctional melanocytic component is not identified, it is likely to be a recurrence/metastasis; the tumour cells are positive for S-100, HMB-45 and Melan-A.

2. Left groin, sentinel lymph node

The sections show a lymph node. No evidence of malignancy is seen in the sections stained with haematoxylin-eosin, S-100 and HMB-45.

SUMMARY

1. Skin, left thigh

Melanoma.

2. Left groin, sentinel lymph node

No evidence of malignancy in 1 lymph node.

REPORTED BY: Dr

	Yes	No
I-PAA Discrepancy		

hr 3/30/11

Printed

Source: NCI Genomic Data Commons file 063a0de4-b267-447c-8f7a-0ad24956d26b (TCGA-EE-A20B.79A6F01B-8093-4EEF-8017-FB32378F85C6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).